Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3324, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3324-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time:

Surgical Pathology

Histopathological Examination

Path#:
Collected: Received: Complete:

Pre-Op Diagnosis : Hematuria/Renal Mass
Order Physician :
Specimens : Kidney, Right
Frozen Diagnosis :

Report : GROSS EXAMINATION:

The specimen is received in a container labeled with the name of the patient and labeled as kidney, right. The specimen consists of a kidney and attached perinephric fat which measures en bloc 22 x 13 x 8 cm and weighs 1154 g. The ureter and vascular margins of resection are submitted in block 1. Sectioning into the kidney shows a central oval, golden-yellow, focally hemorrhagic mass which measures 6.3 x 5 x 4 cm. The mass bulges against the capsule but does not grossly appear to extend through the capsule. Sections of the capsule are submitted in blocks 2-3. Sections of the mass are submitted in blocks 4-8. The cortex averages 0.7 cm. The pelvis and calyces are not grossly dilated. A random section of kidney is submitted in block nine. The attached fat is dissected and no lymph nodes or adrenal tissue is identified.

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy.
LATERALITY: Right kidney.
TUMOR SITE: Middle.
FOCALITY: Unifocal.
TUMOR SIZE (LARGEST TUMOR IF MULTIPLE): 6.3 x 5 x 4 cm.
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney.
HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma.
HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): G3.
EXTENT OF INVASION
PRIMARY TUMOR (PT): pT1b (tumor 4-7 cm, limited to kidney).
REGIONAL LYMPH NODES (PN): pNX (cannot be assessed).
DISTANT METASTASIS (PM): pMX (cannot be assessed).
MARGINS: Uninvolved by invasive carcinoma.
ADRENAL GLAND: Not present.

[page 2 of 2]
VENOUS (LARGE VESSEL) INVASION (v): Absent.
LYMPHATIC (SMALL VESSEL) INVASION (L): Absent.
[T-71000 M-83103 189.0 P3-44070]

ptNM summary: pT1bNXMX.

Intradepartmental consultation was obtained.

Electronically Signed by:

Source: NCI Genomic Data Commons file 4483b891-ff8c-4a65-b6d1-5a65a971162d (TCGA-A3-3324.94610ED5-F7DC-4D74-A03E-ECC8DF8009C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).